Gene-level copy-number profile of tumor specimen TCGA-OR-A5JK-01A from TCGA case TCGA-OR-A5JK, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 49.9 years (18,214 days).
Specimen TCGA-OR-A5JK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ACC.7293f226-7455-428c-b603-9050a23c9742.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-OR-A5JK-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7f4a4132-85a1-48ac-a71a-8604ea0c000c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 21; copy number 2: 31,311; copy number 3: 2,813; copy number 4: 25,456; copy number 5: 33; copy number 6: 172.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-OR-A5JK-01A-11D-A29H-01): tumor purity 0.74, ploidy 1.48, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:115,837,870–115,838,159, 1 gene: RN7SL815P.
- chr3:116,552,473–116,568,264, 1 gene (within-gene range 0–1): LINC00903.
- chr3:116,850,277–116,932,238, 3 genes: MIR4447, AC069504.1, LINC00901.
- chr4:181,064,089–181,159,149, 1 gene: LINC00290.
- chr6:156,776,020–157,210,779, 1 gene (within-gene range 0–2): ARID1B.
- chr6:156,976,294–157,119,706, 2 genes: AL162578.1, AL049820.1.
- chr22:28,992,721–29,061,844, 3 genes: ZNRF3-IT1, ZNRF3-AS1, C22orf31.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 205 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,453,982–60,945,073, 30 genes, copy number 5: PLK2, GAPT, AC008814.1, MIR548AE2, LINC02108, RAB3C, AC016642.1, RPL5P15, AC008852.1, PDE4D, AC092343.1, AC008833.1, NDUFB4P2, MIR582, AC034234.1, RNU6-806P, AC109486.1, SETP21, AC109486.2, PART1, AC109486.3, AC016591.1, DEPDC1B, CAB39P1, AC109133.1, KRT8P31, ELOVL7, ERCC8, GNL3LP1, ERCC8-AS1.
- chr5:73,952,940–82,276,857, 168 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr5:114,055,926–114,668,410, 4 genes, copy number 6 (within-gene range 4–6): KCNN2, RN7SKP89, AC010230.1, LINC01957.
- chr16:47,724,568–47,908,431, 3 genes, copy number 5: LINC02133, AC141846.1, LINC02192.

Autosomal genes at a single copy (total copy number 1): 19. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
